Somatic mutation profile of tumor specimen 0DQZ3R from CCDI case PBCFUR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.0 years (5,465 days).
Specimen 0DQZ3R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57918b0b-b22a-47b8-b0c9-bafc72c55967.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e129b2f-1cdf-4082-ba57-192e97b274c4

The open-access MAF lists 431 somatic variants for this specimen: 255 protein-altering or splice-affecting, 83 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 83, Intron 55, Frame Shift Del 23, 3'UTR 19, Frame Shift Ins 17, Nonsense Mutation 16, 5'UTR 14, In Frame Del 7, Splice Region 5, 5'Flank 4, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 38/868 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123105, CM950052, CM960042, COSV99497942; ClinVar: pathogenic; called by muse, mutect2
- GJB2 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 259/759 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894402, CM980925; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1893dup p.R632Qfs*20 | Frame Shift Ins (INS) | VAF 186/613 reads (30%) | catalogued as rs397508104; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PDGFRA | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 689/1271 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57265219, COSV57268286, COSV57271923; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 697/1463 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SETD5 | c.3520C>T p.R1174* | Nonsense Mutation (SNP) | VAF 348/1099 reads (32%) | catalogued as rs1559496157, COSV104404930; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 922/1076 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.2149G>A p.V717M (on ENST00000614293; = p.V687M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 194/634 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs1244535900; called by muse, mutect2, varscan2
- AC008397.2 | c.1782G>T p.E594D | Missense Mutation (SNP) | VAF 238/501 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760522234; called by muse, mutect2, varscan2
- ACOT12 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 197/1356 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs1275849476; called by muse, mutect2, varscan2
- ADGRL1 | c.4253G>C p.G1418A (on ENST00000340736 / NM_001008701.3; = p.G1413A on NM_014921.5) | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1568560223; called by mutect2, varscan2
- ADGRV1 | c.16249G>A p.V5417I | Missense Mutation (SNP) | VAF 780/1615 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs375876245; called by muse, mutect2, varscan2
- AGAP1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 435/1339 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV58328554; called by muse, mutect2, varscan2
- AHI1 | c.192C>T p.P64= | Splice Region (SNP) | VAF 213/1571 reads (14%) | catalogued as rs776796882; called by muse, mutect2, varscan2
- AHNAK | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 279/875 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs369654662; called by muse, mutect2, varscan2
- AKAP8L | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 198/659 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.704); catalogued as rs1287773316, COSV101275793; called by muse, mutect2, varscan2
- AMOTL2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 50/898 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51438167; called by muse, mutect2
- APCS | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 322/1188 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.01); catalogued as rs567804198; called by muse, mutect2, varscan2
- APOBEC1 | c.208T>A p.F70I | Missense Mutation (SNP) | VAF 242/516 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs1555093510, COSV57549846; called by mutect2, varscan2
- ARG2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 126/541 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs747904249, COSV104370240; called by muse, mutect2, varscan2
- ARHGAP11A | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 249/625 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs143960378, COSV64381612; called by muse, mutect2, varscan2
- ARHGEF25 | c.12dup p.H5Afs*29 | Frame Shift Ins (INS) | VAF 70/214 reads (33%) | catalogued as rs747120740; called by mutect2, varscan2
- ASTL | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 58/1168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151115044; called by muse, mutect2
- BBS5 | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 230/835 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs933203578; called by muse, mutect2, varscan2
- BMPR2 | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 306/1211 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.055); catalogued as rs147960425; called by muse, mutect2, varscan2
- C11orf95 | c.1512del p.G505Afs*86 | Frame Shift Del (DEL) | VAF 137/330 reads (42%) | catalogued as rs1228346103; called by mutect2, pindel, varscan2
- C2CD2 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 290/944 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs755868537; called by muse, mutect2, varscan2
- C2CD4C | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 92/271 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as rs1318968948; called by muse, mutect2, varscan2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 126/462 reads (27%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CAVIN2 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 405/852 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58423137; called by muse, mutect2, varscan2
- CCDC40 | c.3338G>A p.R1113H | Missense Mutation (SNP) | VAF 184/637 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368814379; called by muse, mutect2, varscan2
- CD163L1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 204/481 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs568854207, COSV58011767; called by muse, mutect2, varscan2
- CD207 | c.293dup p.N98Kfs*2 | Frame Shift Ins (INS) | VAF 378/1148 reads (33%) | catalogued as rs1318090693; called by mutect2, varscan2
- CD300LD | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 265/864 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs770203986, COSV60084284; called by muse, mutect2, varscan2
- CEBPE | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 210/426 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1429530896; called by muse, varscan2
- CEL | c.2115dup p.V706Rfs*6 (on ENST00000673714; = p.V703Rfs*6 on NM_001807.6) | Frame Shift Ins (INS) | VAF 40/186 reads (22%) | catalogued as rs768251399; called by mutect2, varscan2
- CENPF | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 143/1210 reads (12%) | catalogued as rs199800194; called by muse, mutect2, varscan2
- CENPL | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 188/1585 reads (12%) | catalogued as rs994018186, COSV61891896; called by muse, mutect2, varscan2
- CENPT | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 243/638 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs892367026, COSV99534919; called by muse, mutect2, varscan2
- CEP112 | c.2018C>T p.T673M | Missense Mutation (SNP) | VAF 447/1007 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs747385055; called by muse, mutect2, varscan2
- CFAP74 | c.4583C>T p.T1528M | Missense Mutation (SNP) | VAF 403/892 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs765513822; called by muse, mutect2, varscan2
- CHD3 | c.4142G>A p.R1381H | Missense Mutation (SNP) | VAF 87/703 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1165994865, COSV100391656; called by muse, mutect2, varscan2
- CHM | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 535/1193 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1486342443; called by muse, mutect2, varscan2
- CHST12 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 235/854 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs377228845; called by muse, mutect2, varscan2
- CNR2 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 310/1172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs202124598; called by muse, mutect2
- CPQ | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 371/903 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs571560641, COSV55154233; called by muse, mutect2, varscan2
- CPT1B | c.2234C>T p.T745M | Missense Mutation (SNP) | VAF 242/519 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550207536, COSV100376593; called by muse, mutect2, varscan2
- CREB3 | c.514_516del p.K172del | In Frame Del (DEL) | VAF 340/768 reads (44%) | catalogued as rs1312276366; called by pindel, varscan2
- CRYGB | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 446/919 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs545870578, COSV53681007; called by muse, mutect2, varscan2
- DDX60L | c.2300C>T p.T767M | Missense Mutation (SNP) | VAF 316/1012 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs779875406; called by muse, mutect2, varscan2
- DEF8 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 206/491 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs757169037, COSV51919834; called by muse, mutect2, varscan2
- DNAH8 | c.11842G>A p.A3948T | Missense Mutation (SNP) | VAF 456/1034 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59443812; called by muse, mutect2, varscan2
- DOCK6 | c.4913G>A p.R1638H | Missense Mutation (SNP) | VAF 282/897 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs766688657, COSV99625337; called by muse, mutect2, varscan2
- DPEP3 | c.285C>T p.D95= | Splice Region (SNP) | VAF 350/909 reads (39%) | catalogued as rs777421793; called by muse, mutect2, varscan2
- DPP7 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 340/747 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1459495872, COSV65370929; called by muse, mutect2, varscan2
- DST | c.20377C>T p.R6793C (on ENST00000361203 / NM_001374722.1; = p.R4490C on NM_015548.5) | Missense Mutation (SNP) | VAF 198/1552 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340867606; called by muse, mutect2, varscan2
- DYNLL2 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 701/1423 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV73897074; called by muse, mutect2, varscan2
- DYSF | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 456/965 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); catalogued as rs769802282; called by muse, mutect2, varscan2
- ELOA2 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV55294807; called by muse, mutect2, varscan2
- ENPP5 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 349/1072 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs560244869; called by muse, mutect2, varscan2
- EPB41L2 | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 144/1098 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as rs748999213, COSV61353035; called by muse, mutect2, varscan2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 245/599 reads (41%) | catalogued as rs755604942; called by mutect2, pindel, varscan2
- EVPL | c.4156G>A p.E1386K | Missense Mutation (SNP) | VAF 201/608 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.146); catalogued as rs949204383; called by muse, mutect2, varscan2
- FAM205A | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 196/612 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs778196529, COSV66490141; called by muse, mutect2, varscan2
- FAM83H | c.2787dup p.V930Rfs*41 | Frame Shift Ins (INS) | VAF 146/453 reads (32%) | catalogued as rs781931295; called by mutect2, pindel, varscan2
- FAM91A1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 652/1446 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1012721253, COSV58236363; called by muse, mutect2, varscan2
- FBXW11 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 360/1289 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV51608765; called by muse, mutect2, varscan2
- FLRT1 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 258/831 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.162); catalogued as rs773022140; called by muse, mutect2, varscan2
- FMR1 | c.1062dup p.H355Tfs*15 | Frame Shift Ins (INS) | VAF 315/900 reads (35%) | catalogued as rs781892436; called by mutect2, varscan2
- FRMD5 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 32/1324 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1200093582; called by muse, mutect2
- FUZ | c.1169T>G p.L390R | Missense Mutation (SNP) | VAF 218/456 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226811597, COSV58241812; called by muse, mutect2, varscan2
- GATAD2A | c.1610C>T p.T537M | Missense Mutation (SNP) | VAF 85/703 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs549651871; called by muse, mutect2, varscan2
- GIPC1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 221/457 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs747232753, COSV100599988; called by muse, mutect2, varscan2
- GLIS3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 109/261 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775044065, COSV60930310; called by muse, mutect2
- GOLGA8H | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 107/547 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs776844064; called by mutect2, varscan2
- GSPT1 | c.448G>A p.E150K (on ENST00000420576 / NM_001130007.2; = p.E288K on NM_002094.4) | Missense Mutation (SNP) | VAF 367/930 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs1240209587, COSV70452547; called by muse, mutect2, varscan2
- H1-6 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 678/1382 reads (49%) | catalogued as rs1388346368, COSV58090213; called by muse, mutect2, varscan2
- H2BW2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 517/1093 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as rs781795208; called by muse, mutect2, varscan2
- HDAC10 | c.291G>A p.P97= | Splice Region (SNP) | VAF 138/439 reads (31%) | catalogued as rs763302996, COSV53132217, COSV53134557; called by muse, mutect2, varscan2
- HECW1 | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 59/907 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs929423946, COSV67838087; called by muse, mutect2
- HMCN1 | c.10700G>A p.R3567Q | Missense Mutation (SNP) | VAF 788/1648 reads (48%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); catalogued as rs765175348, COSV54896723; called by muse, mutect2, varscan2
- HSDL2 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 184/1217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561460624; called by muse, mutect2, varscan2
- INPP5J | c.2654G>A p.R885H (on ENST00000331075 / NM_001284285.2; = p.R517H on NM_001002837.2) | Missense Mutation (SNP) | VAF 209/460 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as rs1193345118; called by muse, mutect2, varscan2
- INTS6 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 493/1047 reads (47%) | catalogued as rs577704602; called by muse, mutect2, varscan2
- IQCE | c.1616del p.K539Rfs*25 | Frame Shift Del (DEL) | VAF 696/1088 reads (64%) | catalogued as rs759821884; called by mutect2, varscan2
- ITCH | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 492/1294 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs781351779, COSV52939019; called by muse, mutect2, varscan2
- ITPR1 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 387/1322 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as rs921824131; called by muse, mutect2, varscan2
- JAG2 | c.3056C>T p.S1019L | Missense Mutation (SNP) | VAF 38/602 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as rs189467562; called by muse, mutect2
- KAT7 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 605/1226 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52014655; called by muse, mutect2, varscan2
- KBTBD13 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 231/580 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs759710350, COSV101416689; called by muse, mutect2, varscan2
- KCNC1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 218/423 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772153533, COSV99788977; called by muse, mutect2, varscan2
- KCNH3 | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1368098030; called by muse, mutect2
- KIAA1549 | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 190/1615 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs745323375, COSV54322989, COSV99650071; called by muse, mutect2, varscan2
- KIAA1755 | c.3324G>A p.W1108* | Nonsense Mutation (SNP) | VAF 278/687 reads (40%) | catalogued as rs776417747; called by muse, mutect2, varscan2
- KIDINS220 | c.3386C>T p.T1129M | Missense Mutation (SNP) | VAF 174/1168 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs775892620, COSV56750260; called by muse, mutect2, varscan2
- KRT86 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 280/1470 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs567721642; called by muse, varscan2
- LAS1L | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 360/687 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV56707541; called by muse, mutect2, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 242/886 reads (27%) | catalogued as rs775423572; called by mutect2, varscan2
- LRRN4 | c.566del p.G189Afs*47 | Frame Shift Del (DEL) | VAF 182/495 reads (37%) | catalogued as rs780053537; called by mutect2, pindel, varscan2
- LYST | c.4297C>T p.R1433W | Missense Mutation (SNP) | VAF 545/1789 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs772648319; called by muse, mutect2, varscan2
- MED19 | c.618_620del p.E207del | In Frame Del (DEL) | VAF 252/934 reads (27%) | catalogued as rs1289593915; called by pindel, varscan2
- MFN1 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 713/1643 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs575310683; called by muse, mutect2, varscan2
- MISP | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs372409482; called by muse, mutect2, varscan2
- MKNK1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 363/822 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1553204022; called by muse, mutect2, varscan2
- MLXIPL | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 217/498 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs560940935; called by muse, mutect2, varscan2
- MOGAT3 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 284/600 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs763725968, COSV56173670; called by muse, mutect2, varscan2
- MUC5B | c.16207G>A p.A5403T | Missense Mutation (SNP) | VAF 158/540 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs746569461; called by muse, mutect2, varscan2
- MYADM | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.59); catalogued as rs1246716963, COSV61240121; called by muse, mutect2, varscan2
- MYBBP1A | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 116/740 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as rs368435100; called by muse, mutect2, varscan2
- MYCBP2 | c.580G>A p.V194M (on ENST00000357337; = p.V232M on NM_015057.5) | Missense Mutation (SNP) | VAF 693/1427 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs762213576; called by muse, mutect2, varscan2
- MYO7B | c.3730G>A p.V1244M | Missense Mutation (SNP) | VAF 33/813 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as rs745896234; called by muse, mutect2
- NALCN | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 422/1365 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs867467226, COSV51959339; called by muse, mutect2, varscan2
- NMUR2 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 54/880 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as COSV54920982; called by muse, mutect2
- NOTCH2 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 294/885 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs782154624, COSV99862761; called by muse, mutect2, varscan2
- OR2AG1 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 428/1332 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1341819803; called by muse, mutect2, varscan2
- PALD1 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 50/735 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.08); catalogued as rs767240221, COSV54970450, COSV54971844, COSV54976023; called by muse, mutect2
- PARD3B | c.3305G>A p.R1102Q (on ENST00000406610 / NM_001302769.2; = p.R1033Q on NM_057177.7) | Missense Mutation (SNP) | VAF 214/772 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1156808441; called by muse, mutect2, varscan2
- PCDHGA12 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 231/610 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs369088426; called by muse, mutect2, varscan2
- PCLO | c.8788G>A p.V2930I | Missense Mutation (SNP) | VAF 607/1898 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs769891041, COSV100427079, COSV61674645; called by muse, mutect2, varscan2
- PCNX2 | c.3019G>A p.V1007I | Missense Mutation (SNP) | VAF 77/1078 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs535193160, COSV50787122; called by muse, mutect2
- PDE1C | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 563/1191 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs775393302, COSV58502926; called by muse, mutect2, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 184/662 reads (28%) | catalogued as rs761575760; called by pindel, varscan2
- PIP | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 794/1590 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as rs1487072188; called by muse, mutect2, varscan2
- PLEKHF1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 191/379 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1302128957; called by muse, mutect2, varscan2
- PLEKHG4B | c.1975C>T p.R659* (on ENST00000283426; = p.R1015* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 218/744 reads (29%) | catalogued as rs374657496; called by muse, mutect2, varscan2
- PODN | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 188/728 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753880782; called by muse, mutect2, varscan2
- PPL | c.2468G>A p.S823N | Missense Mutation (SNP) | VAF 238/629 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1172307999; called by muse, mutect2, varscan2
- PRDM15 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 76/515 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54152367; called by muse, mutect2, varscan2
- PRDM16 | c.3794C>T p.S1265L | Missense Mutation (SNP) | VAF 456/930 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs771454903; called by muse, mutect2, varscan2
- PRR35 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 113/312 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs924238715; called by muse, mutect2, varscan2
- PRSS53 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 108/789 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs574074840, COSV54925517; called by muse, mutect2, varscan2
- PYGL | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 243/925 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs372046135, COSV104370008; called by muse, mutect2, varscan2
- RABGAP1 | c.2789dup p.N930Kfs*7 | Frame Shift Ins (INS) | VAF 87/762 reads (11%) | catalogued as rs749213218; called by mutect2, varscan2
- RAD1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 487/1128 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561168024, COSV57714847; called by muse, mutect2, varscan2
- RAD23B | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 72/1671 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100787689; called by muse, mutect2
- RGPD2 | c.3827G>A p.R1276H | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs765756600; called by mutect2, varscan2
- ROBO4 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 188/694 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.169); catalogued as rs1040635118, COSV60623933; called by muse, mutect2, varscan2
- RYR1 | c.4115C>T p.A1372V | Missense Mutation (SNP) | VAF 134/370 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs370966353; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SASH1 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 170/490 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as rs937939084; called by muse, mutect2, varscan2
- SEMA4B | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 296/810 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.169); catalogued as rs758326798; called by muse, mutect2, varscan2
- SHISA2 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 102/316 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs753752474; called by muse, mutect2, varscan2
- SIGLEC6 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 192/646 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs1227280398; called by mutect2, varscan2
- SLC26A6 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 372/764 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs368223579; called by muse, mutect2, varscan2
- SLC4A2 | c.2890G>A p.V964I | Missense Mutation (SNP) | VAF 331/1077 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs775992236; called by muse, mutect2, varscan2
- SLC5A5 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 63/438 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs779726674, COSV55834521; called by muse, mutect2, varscan2
- SLC9C1 | c.29del p.F10Sfs*11 | Frame Shift Del (DEL) | VAF 343/715 reads (48%) | catalogued as rs749004401; called by mutect2, varscan2
- SLITRK5 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 174/539 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371327441; called by muse, mutect2, varscan2
- SNED1 | c.1891G>A p.G631S | Missense Mutation (SNP) | VAF 325/672 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768738014; called by muse, mutect2, varscan2
- SOCS5 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 398/1185 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60603916, COSV60604974; called by muse, mutect2, varscan2
- SOHLH2 | c.412_414del p.T138del | In Frame Del (DEL) | VAF 410/894 reads (46%) | catalogued as rs1208847825; called by pindel, varscan2
- SPPL2C | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 116/988 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs369336082, COSV61291941; called by muse, mutect2, varscan2
- SPTBN4 | c.5705G>A p.R1902Q | Missense Mutation (SNP) | VAF 357/734 reads (49%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs1014670253; called by muse, mutect2, varscan2
- SPTSSB | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 617/1297 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.659); catalogued as rs144350794, COSV100780643, COSV63218959; called by muse, mutect2, varscan2
- STOX1 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs746103012, COSV53813216; called by muse, mutect2, varscan2
- SULF1 | c.224C>G p.A75G | Missense Mutation (SNP) | VAF 277/762 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs758804596, COSV52684066, COSV52690117; called by muse, mutect2, varscan2
- SYTL4 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 407/866 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1269600130, COSV52168196; called by muse, mutect2, varscan2
- SYVN1 | c.1603del p.R535Gfs*96 (on ENST00000377190 / NM_172230.3; = p.R534Gfs*96 on NM_032431.3) | Frame Shift Del (DEL) | VAF 270/798 reads (34%) | catalogued as COSV53697242; called by mutect2, varscan2
- TAB2 | c.1724G>T p.R575M | Missense Mutation (SNP) | VAF 331/1122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53852831; called by muse, mutect2, varscan2
- TADA3 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 407/820 reads (50%) | catalogued as rs766457564; called by muse, mutect2, varscan2
- TES | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 490/1097 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs755575154, COSV64042141; called by muse, mutect2, varscan2
- TFIP11 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 320/993 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs1569165077; called by muse, mutect2, varscan2
- THBS2 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 324/637 reads (51%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.999); catalogued as COSV64681898; called by mutect2, varscan2
- TIE1 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 60/525 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs888346167, COSV65248458; called by muse, mutect2, varscan2
- TLR6 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 509/1624 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs774046904; called by muse, mutect2, varscan2
- TNFRSF9 | c.345dup p.G116Rfs*3 | Frame Shift Ins (INS) | VAF 100/645 reads (16%) | catalogued as rs752649731; called by mutect2, varscan2
- TP73 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 155/476 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs758257291; called by muse, mutect2, varscan2
- TRIM17 | c.1117_1119del p.N373del | In Frame Del (DEL) | VAF 61/498 reads (12%) | catalogued as rs770919705; called by mutect2, pindel, varscan2
- TSEN54 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 212/435 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1189741192; called by muse, mutect2, varscan2
- UBR5 | c.4058C>T p.P1353L | Missense Mutation (SNP) | VAF 134/813 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as rs578173678, COSV55292447, COSV99641346; called by muse, mutect2, varscan2
- UHRF1 | c.982G>A p.D328N (on ENST00000612630 / NM_001290050.1; = p.D341N on NM_013282.4) | Missense Mutation (SNP) | VAF 246/711 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs1027058439; called by muse, mutect2, varscan2
- UPF1 | c.1458+6C>T | Splice Region (SNP) | VAF 313/714 reads (44%) | catalogued as rs746222060; called by muse, mutect2, varscan2
- USP13 | c.1896dup p.I633Hfs*5 | Frame Shift Ins (INS) | VAF 228/758 reads (30%) | catalogued as rs780272979; called by mutect2, varscan2
- USP24 | c.5687G>A p.R1896H | Missense Mutation (SNP) | VAF 398/1202 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749995845; called by muse, mutect2, varscan2
- UTP20 | c.8239del p.M2747* | Frame Shift Del (DEL) | VAF 92/665 reads (14%) | catalogued as rs1166902251; called by mutect2, varscan2
- UTP25 | c.1873G>A p.V625M | Missense Mutation (SNP) | VAF 1026/1819 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774606875, COSV71966142; called by muse, mutect2, varscan2
- VIM | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 704/1494 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs1452626097, COSV56406480; called by muse, mutect2, varscan2
- WDR81 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 316/709 reads (45%) | catalogued as rs779405050, COSV58486374, COSV58487931; called by muse, mutect2, varscan2
- WT1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 190/423 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV60073353; called by muse, mutect2, varscan2
- WWC3 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 282/657 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764722450; called by muse, mutect2, varscan2
- ZBTB40 | c.1583_1584del p.S528Cfs*54 | Frame Shift Del (DEL) | VAF 443/1195 reads (37%) | catalogued as rs1288159892; called by pindel, varscan2
- ZC3H12D | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 194/532 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66324370; called by muse, mutect2, varscan2
- ZNF541 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 155/434 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193012414; called by muse, mutect2, varscan2
- ZNF654 | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 208/1736 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772062287, COSV58806386; called by muse, mutect2, varscan2
- ZNF687 | c.2987G>A p.R996H | Missense Mutation (SNP) | VAF 149/598 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.982); catalogued as rs147072139; called by muse, mutect2, varscan2
- ZNF689 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 268/666 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs755240529, COSV54909767; called by muse, mutect2, varscan2
- ZNF880 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 232/762 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs1425290341; called by muse, mutect2, varscan2
- ADARB2 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 265/571 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID1B | c.5243G>T p.S1748I | Missense Mutation (SNP) | VAF 544/1110 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARSJ | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 354/1170 reads (30%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASPM | c.6262_6264del p.K2088del | In Frame Del (DEL) | VAF 727/1481 reads (49%) | called by mutect2, pindel, varscan2
- ATRX | c.2381del p.K794Rfs*9 | Frame Shift Del (DEL) | VAF 350/1405 reads (25%) | called by pindel, varscan2
- BUB1B | c.3069del p.F1023Lfs*9 | Frame Shift Del (DEL) | VAF 395/1157 reads (34%) | called by mutect2, pindel, varscan2
- CNOT1 | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 382/1136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CX3CL1 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 207/601 reads (34%) | called by muse, mutect2, varscan2
- DHX30 | c.2613dup p.Q872Afs*60 (on ENST00000445061 / NM_138615.3; = p.Q833Afs*60 on NM_014966.3) | Frame Shift Ins (INS) | VAF 172/549 reads (31%) | called by mutect2, pindel, varscan2
- DHX34 | c.2279del p.P760Qfs*12 | Frame Shift Del (DEL) | VAF 126/413 reads (31%) | called by mutect2, pindel, varscan2
- DOCK7 | c.1465C>A p.L489I | Missense Mutation (SNP) | VAF 250/949 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- EHBP1 | c.2986dup p.T996Nfs*6 | Frame Shift Ins (INS) | VAF 584/1433 reads (41%) | called by mutect2, pindel, varscan2
- GANAB | c.174_175del p.P59Ifs*13 | Frame Shift Del (DEL) | VAF 69/677 reads (10%) | called by pindel, varscan2
- GFRA1 | c.606G>T p.K202N | Missense Mutation (SNP) | VAF 235/597 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- GPA33 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 304/549 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HEATR1 | c.3948G>A p.P1316= | Splice Region (SNP) | VAF 425/701 reads (61%) | called by muse, mutect2, varscan2
- HPN | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 240/567 reads (42%) | called by muse, mutect2, varscan2
- HRNR | c.1252T>G p.S418A | Missense Mutation (SNP) | VAF 76/955 reads (8%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.981); called by muse, mutect2
- HYDIN | c.3133G>A p.V1045I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- IQSEC2 | c.2774C>T p.P925L (on ENST00000642864 / NM_001111125.3; = p.P720L on NM_015075.2) | Missense Mutation (SNP) | VAF 434/843 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ITPR1 | c.8027C>T p.P2676L (on ENST00000354582; = p.P2621L on NM_002222.7) | Missense Mutation (SNP) | VAF 315/796 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- ITPRIPL2 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 163/368 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA1217 | c.2753C>T p.A918V | Missense Mutation (SNP) | VAF 325/652 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- KLHL5 | c.717_719del p.S240del | In Frame Del (DEL) | VAF 82/864 reads (9%) | called by pindel, varscan2
- KMT5B | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 178/1354 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT17 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 113/869 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- LRFN5 | c.1492A>G p.T498A | Missense Mutation (SNP) | VAF 468/1006 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- MACF1 | c.1248_1249del p.K417Ifs*27 | Frame Shift Del (DEL) | VAF 341/1212 reads (28%) | called by pindel, varscan2
- MARCHF7 | c.2007+5_2007+8del p.X669_splice | Splice Site (DEL) | VAF 248/847 reads (29%) | called by pindel, varscan2
- MCF2L | c.2189A>G p.N730S (on ENST00000375608; = p.N698S on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/452 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MINDY2 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 129/330 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MSR1 | c.1287T>A p.C429* | Nonsense Mutation (SNP) | VAF 999/2367 reads (42%) | called by muse, mutect2, varscan2
- MUC1 | c.3320T>C p.V1107A (on ENST00000611571 / NM_001371720.1; = p.V118A on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/776 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); called by muse, mutect2
- MYORG | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 249/551 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NF1 | c.1882del p.Y628Tfs*3 | Frame Shift Del (DEL) | VAF 281/1063 reads (26%) | called by pindel, varscan2
- OXCT1 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 126/924 reads (14%) | called by muse, mutect2, varscan2
- PCDHB15 | c.1849G>A p.V617M | Missense Mutation (SNP) | VAF 131/331 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- PEX1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 375/1137 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- PHF3 | c.2884del p.I962Lfs*23 | Frame Shift Del (DEL) | VAF 520/1330 reads (39%) | called by mutect2, pindel, varscan2
- PIBF1 | c.1482dup p.L495Ifs*10 | Frame Shift Ins (INS) | VAF 359/914 reads (39%) | called by mutect2, pindel, varscan2
- PKHD1 | c.4593del p.F1531Lfs*61 | Frame Shift Del (DEL) | VAF 601/1490 reads (40%) | called by mutect2, pindel, varscan2
- POGZ | c.3837del p.K1279Nfs*31 | Frame Shift Del (DEL) | VAF 630/1202 reads (52%) | called by mutect2, varscan2
- PPME1 | c.880dup p.T294Nfs*18 | Frame Shift Ins (INS) | VAF 183/1544 reads (12%) | called by mutect2, pindel, varscan2
- PRRC2C | c.7270C>T p.Q2424* (on ENST00000367742; = p.Q2422* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 265/844 reads (31%) | called by muse, mutect2, varscan2
- PTF1A | c.786_787insC p.S263Lfs*8 | Frame Shift Ins (INS) | VAF 58/486 reads (12%) | called by mutect2, pindel*, varscan2
- PYY | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 141/301 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- RBCK1 | c.656C>T p.A219V (on ENST00000356286 / NM_031229.4; = p.A177V on NM_006462.6) | Missense Mutation (SNP) | VAF 354/877 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RNF10 | c.2388del p.K796Nfs*46 | Frame Shift Del (DEL) | VAF 212/650 reads (33%) | called by mutect2, pindel, varscan2
- RPL18 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 169/526 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- RYR2 | c.3317A>G p.E1106G | Missense Mutation (SNP) | VAF 151/1149 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- SCAMP2 | c.679del p.C227Vfs*3 | Frame Shift Del (DEL) | VAF 242/618 reads (39%) | called by mutect2, varscan2
- SETD2 | c.7143del p.S2382Lfs*29 | Frame Shift Del (DEL) | VAF 519/1352 reads (38%) | called by mutect2, pindel, varscan2
- SMARCC2 | c.956+2T>C p.X319_splice | Splice Site (SNP) | VAF 133/344 reads (39%) | called by muse, mutect2, varscan2
- SMARCC2 | c.881dup p.N295Kfs*3 | Frame Shift Ins (INS) | VAF 178/566 reads (31%) | called by mutect2, pindel, varscan2
- SNX29 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 105/291 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SNX9 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 445/1349 reads (33%) | called by muse, mutect2, varscan2
- SOX3 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 381/883 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TBC1D14 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 139/1136 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TET3 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 353/1131 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TLL1 | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 354/726 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMC4 | c.1562C>T p.A521V (on ENST00000617472 / NM_001145303.3; = p.A515V on NM_144686.4) | Missense Mutation (SNP) | VAF 160/342 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, varscan2
- TRIB2 | c.724del p.V242* | Frame Shift Del (DEL) | VAF 291/696 reads (42%) | called by mutect2, pindel, varscan2
- TSHR | c.290_292del p.F97del | In Frame Del (DEL) | VAF 376/1086 reads (35%) | called by mutect2, pindel, varscan2
- VPS45 | c.1363G>T p.G455* | Nonsense Mutation (SNP) | VAF 437/875 reads (50%) | called by muse, mutect2, varscan2
- WWC2 | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 433/1380 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- XIRP1 | c.1901C>A p.P634H | Missense Mutation (SNP) | VAF 307/693 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ZNF280B | c.47A>G p.N16S | Missense Mutation (SNP) | VAF 614/1320 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF668 | c.1165dup p.E389Gfs*7 | Frame Shift Ins (INS) | VAF 131/447 reads (29%) | called by mutect2, pindel, varscan2
- ZNF784 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ALDH5A1 | c.1197C>T p.A399= | Silent (SNP) | VAF 332/713 reads (47%) | catalogued as rs747534238, COSV62373271; called by muse, mutect2, varscan2
- ANO7 | c.585A>G p.L195= (on ENST00000274979; = p.L141= on NM_001370694.2) | Silent (SNP) | VAF 86/268 reads (32%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.147C>T p.C49= | Silent (SNP) | VAF 126/914 reads (14%) | catalogued as rs754749619, COSV99137488; called by muse, mutect2, varscan2
- BTBD11 | c.3180C>T p.N1060= (on ENST00000280758 / NM_001018072.2; = p.N597= on NM_001017523.2) | Silent (SNP) | VAF 266/817 reads (33%) | catalogued as rs138617821, COSV55025421; called by muse, mutect2, varscan2
- CCDC27 | c.390G>A p.T130= | Silent (SNP) | VAF 46/1131 reads (4%) | catalogued as rs753167186, COSV53903846; called by muse, mutect2
- CCDC85C | c.336G>A p.A112= | Silent (SNP) | VAF 189/433 reads (44%) | catalogued as rs1450754042; called by muse, mutect2, varscan2
- CELF1 | c.1119G>A p.A373= (on ENST00000358597 / NM_001376422.1; = p.A369= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 367/1244 reads (30%) | catalogued as rs925447400, COSV100136608; called by muse, mutect2, varscan2
- CES3 | c.279G>A p.A93= | Silent (SNP) | VAF 286/744 reads (38%) | catalogued as rs1359164004, COSV57592965; called by muse, mutect2, varscan2
- COL6A3 | c.5394C>T p.R1798= | Silent (SNP) | VAF 288/814 reads (35%) | catalogued as rs202086524, COSV55099755; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CRTC1 | c.993G>A p.P331= | Silent (SNP) | VAF 64/608 reads (11%) | catalogued as rs768939895; called by muse, mutect2, varscan2
- CSE1L | c.2865G>A p.A955= | Silent (SNP) | VAF 638/1621 reads (39%) | catalogued as rs761707393; called by muse, mutect2, varscan2
- CTSE | c.486A>T p.G162= (on ENST00000360218; = p.G157= on NM_001910.4) | Silent (SNP) | VAF 372/691 reads (54%) | called by muse, mutect2, varscan2
- DENND4C | c.3528G>A p.P1176= (on ENST00000434457 / NM_001330640.2; = p.P1127= on NM_017925.7) | Silent (SNP) | VAF 402/1246 reads (32%) | catalogued as rs748938853, COSV100727546; called by muse, mutect2, varscan2
- DNAH10 | c.8343C>T p.D2781= (on ENST00000409039; = p.D2720= on NM_207437.3) | Silent (SNP) | VAF 267/808 reads (33%) | catalogued as rs562971416, COSV68999697; called by muse, varscan2
- DNAH3 | c.9354G>A p.A3118= | Silent (SNP) | VAF 250/574 reads (44%) | catalogued as rs747689443, COSV54532729, COSV99770452; called by mutect2, varscan2
- DUSP8 | c.279G>A p.T93= | Silent (SNP) | VAF 263/519 reads (51%) | catalogued as rs141702492, COSV100524438; called by muse, mutect2, varscan2
- ELMO1 | c.873G>A p.A291= | Silent (SNP) | VAF 436/901 reads (48%) | catalogued as rs1162849478, COSV60327530; called by muse, mutect2, varscan2
- ERCC6L | c.1644A>G p.A548= | Silent (SNP) | VAF 782/1635 reads (48%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.3342C>T p.G1114= | Silent (SNP) | VAF 298/656 reads (45%) | catalogued as rs752734623; called by muse, mutect2, varscan2
- ESPNL | c.285C>T p.C95= | Silent (SNP) | VAF 222/837 reads (27%) | catalogued as rs749485480; called by muse, mutect2
- EVC | c.411G>A p.P137= | Silent (SNP) | VAF 116/1118 reads (10%) | catalogued as rs758770136; called by muse, mutect2, varscan2
- EXOC2 | c.108C>T p.T36= | Silent (SNP) | VAF 102/780 reads (13%) | catalogued as rs376552752; called by muse, mutect2, varscan2
- F13B | c.432A>G p.P144= | Silent (SNP) | VAF 240/1005 reads (24%) | called by muse, mutect2, varscan2
- F2RL3 | c.663G>A p.A221= | Silent (SNP) | VAF 130/340 reads (38%) | catalogued as rs780011923; called by muse, mutect2, varscan2
- FAM155B | c.27C>T p.P9= | Silent (SNP) | VAF 236/493 reads (48%) | catalogued as rs768747110; called by muse, mutect2, varscan2
- FAM78B | c.510G>A p.T170= | Silent (SNP) | VAF 374/1094 reads (34%) | catalogued as rs143651089; called by muse, mutect2, varscan2
- GAREM2 | c.750C>T p.G250= | Silent (SNP) | VAF 266/772 reads (34%) | catalogued as rs1030094532; called by muse, mutect2, varscan2
- GNAQ | c.93G>A p.R31= | Silent (SNP) | VAF 217/783 reads (28%) | catalogued as COSV54128988; called by muse, varscan2
- GOLGA4 | c.3336G>A p.Q1112= | Silent (SNP) | VAF 467/1094 reads (43%) | called by muse, mutect2, varscan2
- H1-7 | c.36G>A p.R12= | Silent (SNP) | VAF 220/619 reads (36%) | catalogued as rs1284144090; called by muse, mutect2, varscan2
- HARS1 | c.363C>T p.G121= | Silent (SNP) | VAF 271/871 reads (31%) | catalogued as rs372293095; called by muse, mutect2, varscan2
- IBSP | c.564C>T p.N188= | Silent (SNP) | VAF 412/1012 reads (41%) | catalogued as rs747404256, COSV56894549; called by muse, mutect2, varscan2
- IL15RA | c.333G>A p.T111= | Silent (SNP) | VAF 262/628 reads (42%) | catalogued as rs200323588; called by muse, mutect2, varscan2
- ITPRID2 | c.789G>A p.T263= | Silent (SNP) | VAF 664/1386 reads (48%) | catalogued as rs1460185864, COSV100238225; called by muse, mutect2, varscan2
- LIMK1 | c.1122C>T p.D374= | Silent (SNP) | VAF 401/1125 reads (36%) | catalogued as rs1366426624; called by muse, mutect2, varscan2
- LRFN1 | c.1938G>A p.S646= | Silent (SNP) | VAF 106/296 reads (36%) | called by muse, mutect2, varscan2
- LRRC4B | c.1254C>T p.D418= | Silent (SNP) | VAF 227/528 reads (43%) | catalogued as rs886178548, COSV65349636; called by muse, mutect2, varscan2
- MAGEB17 | c.579C>T p.G193= | Silent (SNP) | VAF 338/796 reads (42%) | catalogued as rs774542651, COSV61557214; called by muse, mutect2, varscan2
- MAGT1 | c.219C>T p.S73= (on ENST00000618282 / NM_001367916.1; = p.S105= on NM_032121.5) | Silent (SNP) | VAF 426/1256 reads (34%) | catalogued as rs183592456, COSV63780941; called by muse, mutect2, varscan2
- MED15 | c.1818G>A p.P606= (on ENST00000263205 / NM_001003891.3; = p.P566= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/506 reads (10%) | catalogued as rs779470796; called by muse, mutect2, varscan2
- MRC2 | c.3567C>T p.G1189= | Silent (SNP) | VAF 248/723 reads (34%) | catalogued as rs777160267; called by muse, mutect2, varscan2
- MUC12 | c.4995G>A p.T1665= (on ENST00000379442; = p.T1522= on NM_001164462.1) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs551919923; called by mutect2, varscan2
- MYH7B | c.2514G>A p.A838= | Silent (SNP) | VAF 637/1514 reads (42%) | catalogued as rs771382251, COSV53425306; called by muse, mutect2
- NCOR2 | c.2502G>A p.A834= | Silent (SNP) | VAF 168/420 reads (40%) | catalogued as rs775478581, COSV100656809; called by muse, mutect2, varscan2
- NDUFA11 | c.180G>A p.T60= | Silent (SNP) | VAF 229/479 reads (48%) | catalogued as rs745800175; called by muse, mutect2, varscan2
- NPHS1 | c.2724C>T p.N908= | Silent (SNP) | VAF 47/1184 reads (4%) | catalogued as rs200269176, COSV62286302; called by muse, mutect2
- NUDT11 | c.147C>T p.G49= | Silent (SNP) | VAF 320/752 reads (43%) | catalogued as COSV65665236; called by muse, mutect2, varscan2
- OR14C36 | c.618C>T p.G206= | Silent (SNP) | VAF 672/1443 reads (47%) | catalogued as rs767819229, COSV58602456; called by muse, mutect2
- PCDHA5 | c.1773G>A p.A591= | Silent (SNP) | VAF 304/605 reads (50%) | catalogued as rs1554129420, COSV65353451; called by muse, mutect2, varscan2
- PDZD2 | c.6129C>T p.N2043= | Silent (SNP) | VAF 236/755 reads (31%) | catalogued as rs140879154; called by muse, varscan2
- POTEE | c.258C>T p.H86= | Silent (SNP) | VAF 34/327 reads (10%) | catalogued as rs757065263; called by muse, mutect2, varscan2
- PRPF18 | c.591C>T p.G197= | Silent (SNP) | VAF 392/943 reads (42%) | catalogued as rs762318520; called by muse, mutect2, varscan2
- PTGR1 | c.618G>A p.A206= | Silent (SNP) | VAF 365/774 reads (47%) | catalogued as rs765397672, COSV53028670; called by muse, mutect2, varscan2
- PTPRS | c.2205G>A p.T735= | Silent (SNP) | VAF 157/458 reads (34%) | catalogued as rs1568426766, COSV53633654; called by muse, mutect2, varscan2
- PUS1 | c.762G>A p.P254= | Silent (SNP) | VAF 309/791 reads (39%) | catalogued as rs555462060, COSV59035173, COSV59035318; called by muse, mutect2, varscan2
- RALGDS | c.2115C>T p.D705= | Silent (SNP) | VAF 112/828 reads (14%) | catalogued as rs939206593; called by muse, mutect2, varscan2
- RASL12 | c.394C>T p.L132= | Silent (SNP) | VAF 326/841 reads (39%) | called by muse, mutect2, varscan2
- SASS6 | c.1566C>T p.Y522= | Silent (SNP) | VAF 242/954 reads (25%) | called by muse, mutect2, varscan2
- SLC36A2 | c.1230G>T p.V410= | Silent (SNP) | VAF 432/932 reads (46%) | catalogued as COSV58863759; called by muse, mutect2, varscan2
- SLC49A3 | c.1410G>A p.P470= (on ENST00000404286 / NM_001294341.2; = p.P469= on NM_032219.4) | Silent (SNP) | VAF 152/402 reads (38%) | catalogued as rs774923887; called by muse, mutect2, varscan2
- SLC4A11 | c.2451G>A p.P817= | Silent (SNP) | VAF 463/1176 reads (39%) | catalogued as rs575052406, COSV66262874; called by muse, mutect2, varscan2
- SLC5A5 | c.876C>T p.I292= | Silent (SNP) | VAF 250/726 reads (34%) | catalogued as rs750552838, COSV55835831; called by muse, varscan2
- SLC9A6 | c.213C>T p.S71= | Silent (SNP) | VAF 112/286 reads (39%) | catalogued as rs781963863; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLX4 | c.2436C>T p.A812= | Silent (SNP) | VAF 326/805 reads (40%) | catalogued as rs769330696; called by muse, mutect2, varscan2
- SMO | c.1623G>A p.T541= | Silent (SNP) | VAF 240/673 reads (36%) | catalogued as rs1356483889, COSV50832248; called by muse, mutect2, varscan2
- SPG11 | c.7248C>T p.Y2416= | Silent (SNP) | VAF 347/1139 reads (30%) | catalogued as rs763259072, COSV55998291; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPOUT1 | c.408G>A p.G136= | Silent (SNP) | VAF 330/706 reads (47%) | called by muse, mutect2
- SRGAP3 | c.2610C>T p.G870= | Silent (SNP) | VAF 93/802 reads (12%) | catalogued as rs537681085, COSV64530616; called by muse, mutect2, varscan2
- SYT15 | c.435C>T p.D145= | Silent (SNP) | VAF 183/659 reads (28%) | catalogued as rs782314025; called by muse, mutect2, varscan2
- TBC1D2 | c.2382C>T p.L794= | Silent (SNP) | VAF 238/825 reads (29%) | catalogued as rs760745254, COSV59786792; called by muse, mutect2, varscan2
- TBX5 | c.54C>T p.D18= | Silent (SNP) | VAF 144/877 reads (16%) | catalogued as COSV59866397; called by muse, mutect2, varscan2
- TLN1 | c.5949C>T p.S1983= | Silent (SNP) | VAF 326/1064 reads (31%) | catalogued as rs776936711, COSV59209496; called by muse, mutect2, varscan2
- TNFSF14 | c.387C>T p.H129= | Silent (SNP) | VAF 208/626 reads (33%) | catalogued as rs147375196; called by muse, mutect2, varscan2
- TNS3 | c.999C>T p.Y333= | Silent (SNP) | VAF 155/1417 reads (11%) | catalogued as rs756666455; called by muse, mutect2, varscan2
- TPGS1 | c.759G>A p.A253= | Silent (SNP) | VAF 208/622 reads (33%) | called by muse, mutect2, varscan2
- TRAF3 | c.1407G>A p.T469= | Silent (SNP) | VAF 236/489 reads (48%) | catalogued as rs200974693, COSV61027129; called by muse, mutect2, varscan2
- TRIO | c.2964C>T p.C988= | Silent (SNP) | VAF 353/1154 reads (31%) | catalogued as rs144236504, COSV60083753; ClinVar: likely benign; called by muse, mutect2, varscan2
- TULP4 | c.1377G>A p.T459= | Silent (SNP) | VAF 410/723 reads (57%) | catalogued as rs553503808, COSV100893889; called by muse, mutect2, varscan2
- UHRF1 | c.2181T>C p.C727= (on ENST00000612630 / NM_001290050.1; = p.C740= on NM_013282.4) | Silent (SNP) | VAF 481/988 reads (49%) | called by muse, mutect2, varscan2
- ZFHX3 | c.2649C>T p.D883= | Silent (SNP) | VAF 120/577 reads (21%) | catalogued as rs772231000, COSV99213876; called by muse, mutect2, varscan2
- ZNF213 | c.927G>A p.R309= | Silent (SNP) | VAF 180/452 reads (40%) | called by muse, mutect2, varscan2
- ZNF629 | c.1512C>T p.H504= | Silent (SNP) | VAF 147/354 reads (42%) | catalogued as rs189318984; called by muse, mutect2, varscan2
- ZNF853 | c.1770G>A p.T590= | Silent (SNP) | VAF 79/834 reads (9%) | catalogued as rs1228143924, COSV71922798; called by muse, mutect2
- ACIN1 | c.2298-1625del | Intron (DEL) | VAF 63/210 reads (30%) | catalogued as rs1295222048; called by mutect2, varscan2
- ADAM28 | c.1671-87del | Intron (DEL) | VAF 57/155 reads (37%) | called by mutect2, pindel, varscan2
- ADAM9 | c.410+31del | Intron (DEL) | VAF 44/384 reads (11%) | catalogued as rs557600780; called by mutect2, varscan2
- ADGRL1 | c.1630-17G>A | Intron (SNP) | VAF 59/585 reads (10%) | catalogued as rs761903731; called by muse, mutect2, varscan2
- ALAD | c.-3G>A | 5'UTR (SNP) | VAF 459/1027 reads (45%) | catalogued as rs1046615901; called by muse, mutect2, varscan2
- ANKRD28 | c.2783+69del | Intron (DEL) | VAF 103/284 reads (36%) | called by mutect2, pindel, varscan2
- ARPP21 | c.261+201del | Intron (DEL) | VAF 191/783 reads (24%) | called by mutect2, pindel, varscan2
- ASIC5 | c.-31C>T | 5'UTR (SNP) | VAF 175/502 reads (35%) | called by muse, mutect2, varscan2
- ASXL1 | c.883-18C>T | Intron (SNP) | VAF 301/650 reads (46%) | catalogued as rs767111913; called by muse, mutect2, varscan2
- ATG13 | c.-199A>G | 5'UTR (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- ATP13A1 | c.2908+17del | Intron (DEL) | VAF 95/301 reads (32%) | called by mutect2, pindel, varscan2
- B4GALNT1 | c.712+253del | Intron (DEL) | VAF 49/400 reads (12%) | catalogued as rs765724660, COSV57545543; called by mutect2, pindel, varscan2
- BTBD19 | c.483+36G>A | Intron (SNP) | VAF 161/449 reads (36%) | called by muse, mutect2, varscan2
- C11orf58 | c.64-26del | Intron (DEL) | VAF 78/605 reads (13%) | catalogued as rs536903912; called by mutect2, varscan2
- C1orf131 | c.746+69C>T | Intron (SNP) | VAF 79/498 reads (16%) | catalogued as rs367764624; called by muse, mutect2, varscan2
- C2CD4B | c.*87del | 3'UTR (DEL) | VAF 58/110 reads (53%) | catalogued as rs1158224751; called by mutect2, varscan2
- C6orf120 | c.*902T>C | 3'UTR (SNP) | VAF 173/351 reads (49%) | called by muse, mutect2, varscan2
- CACNA1A | c.5547-39dup | Intron (INS) | VAF 67/154 reads (44%) | catalogued as rs778352993; called by mutect2, varscan2
- CAMK1 | c.633-53C>T | Intron (SNP) | VAF 256/400 reads (64%) | catalogued as rs566607774; called by muse, mutect2, varscan2
- CAVIN2 | c.*82C>T | 3'UTR (SNP) | VAF 38/105 reads (36%) | catalogued as rs1285277584; called by muse, mutect2, varscan2
- CBARP | c.1214+66del | Intron (DEL) | VAF 31/208 reads (15%) | catalogued as rs745357441; called by mutect2, varscan2
- CCSER1 | c.2011-35246C>A | Intron (SNP) | VAF 342/1097 reads (31%) | catalogued as COSV61438985; called by muse, mutect2, varscan2
- CELSR2 | c.8510-30C>T | Intron (SNP) | VAF 306/919 reads (33%) | catalogued as rs749630605; called by muse, mutect2, varscan2
- CFLAR | c.*19G>A | 3'UTR (SNP) | VAF 226/575 reads (39%) | catalogued as rs370832816; called by muse, mutect2, varscan2
- CHD8 | c.-52del | 5'UTR (DEL) | VAF 33/134 reads (25%) | catalogued as rs1027707875; called by mutect2, pindel, varscan2
- COX7C | c.*27+80_*27+81dup | Intron (INS) | VAF 79/262 reads (30%) | catalogued as rs1398770333; called by mutect2, varscan2
- CWH43 | c.*12C>G | 3'UTR (SNP) | VAF 44/354 reads (12%) | called by muse, mutect2, varscan2
- DAP3 | c.*13G>A | 3'UTR (SNP) | VAF 351/1052 reads (33%) | catalogued as rs1226601963, COSV58022153; called by muse, mutect2, varscan2
- DCAF5 | c.395+22G>A | Intron (SNP) | VAF 305/581 reads (52%) | called by muse, mutect2, varscan2
- DDX3X | c.104-12_104-11insA | Intron (INS) | VAF 116/521 reads (22%) | catalogued as rs778367553; called by mutect2, pindel, varscan2
- DIS3L2 | c.601+33del | Intron (DEL) | VAF 58/411 reads (14%) | catalogued as rs748662098; called by mutect2, varscan2
- EBF1 | c.-111_-62delinsTCTCTGGTTGGCGTTTTTGTTTCTTTTCTTTTCTTTCTTTTCTTTCC | 5'UTR (DEL) | VAF 27/234 reads (12%) | called by pindel, varscan2*
- EHBP1L1 | c.4284-27del | Intron (DEL) | VAF 31/116 reads (27%) | called by pindel, varscan2
- EPC1 | c.1243-15del | Intron (DEL) | VAF 262/1254 reads (21%) | catalogued as COSV53925622; called by pindel, varscan2
- EVPL | c.*30G>A | 3'UTR (SNP) | VAF 213/543 reads (39%) | catalogued as rs772623211; called by muse, mutect2, varscan2
- F8A1 | c.-9dup | 5'UTR (INS) | VAF 27/65 reads (42%) | called by mutect2, varscan2
- FBXL3 | c.471+67del | Intron (DEL) | VAF 57/372 reads (15%) | catalogued as rs772886626; called by mutect2, varscan2
- FBXW12 | c.-125G>A | 5'UTR (SNP) | VAF 220/714 reads (31%) | catalogued as rs974212672; called by muse, mutect2, varscan2
- FLT4 | c.3331+50G>A | Intron (SNP) | VAF 59/234 reads (25%) | catalogued as rs773135316; called by muse, mutect2, varscan2
- FST | c.953-87A>C | Intron (SNP) | VAF 121/282 reads (43%) | catalogued as COSV99887421; called by muse, mutect2, varscan2
- G3BP1 | c.442+43dup | Intron (INS) | VAF 172/348 reads (49%) | called by mutect2, varscan2
- GABARAP | c.288+51C>T | Intron (SNP) | VAF 167/436 reads (38%) | called by muse, mutect2, varscan2
- GLRA3 | c.*3135del | 3'UTR (DEL) | VAF 54/152 reads (36%) | catalogued as rs569067653; called by mutect2, varscan2
- GLTPP1 | chr11:18188961 G>A | 5'Flank (SNP) | VAF 123/340 reads (36%) | catalogued as rs749061086; called by muse, mutect2, varscan2
- GORAB | chr1:170532139 del A | 5'Flank (DEL) | VAF 52/372 reads (14%) | called by mutect2, pindel, varscan2
- GRIA2 | c.-35del | 5'UTR (DEL) | VAF 148/370 reads (40%) | catalogued as rs74352837; called by mutect2, varscan2
- GRK6 | c.1404+105dup | Intron (INS) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- KCNK16 | chr6:39322633 G>A | 5'Flank (SNP) | VAF 33/94 reads (35%) | called by muse, mutect2, varscan2
- KCTD6 | c.*67del | 3'UTR (DEL) | VAF 86/170 reads (51%) | catalogued as rs916007303; called by mutect2, varscan2
- KDM6A | c.2938+108del | Intron (DEL) | VAF 63/252 reads (25%) | called by mutect2, varscan2
- KLK2 | c.630+95C>A | Intron (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- LIPJ | c.-94G>A | 5'UTR (SNP) | VAF 146/404 reads (36%) | catalogued as rs1018872102, COSV63303337; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85659G>A | Intron (SNP) | VAF 69/1886 reads (4%) | catalogued as COSV72275727; called by muse, mutect2
- MROH7 | c.2964+18G>A | Intron (SNP) | VAF 132/473 reads (28%) | catalogued as rs775121829; called by muse, mutect2, varscan2
- MT1A | c.*98del | 3'UTR (DEL) | VAF 56/180 reads (31%) | catalogued as rs536800910; called by mutect2, varscan2
- MTA2 | c.308+65G>T | Intron (SNP) | VAF 102/301 reads (34%) | called by muse, mutect2, varscan2
- MTMR1 | c.-89C>T | 5'UTR (SNP) | VAF 58/140 reads (41%) | called by muse, mutect2, varscan2
- NOP56 | c.1159+97C>T | Intron (SNP) | VAF 94/232 reads (41%) | catalogued as rs1166170968, COSV100250134; called by muse, mutect2, varscan2
- NPC1 | c.*485del | 3'UTR (DEL) | VAF 264/890 reads (30%) | called by mutect2, pindel, varscan2
- NPR1 | c.*5C>T | 3'UTR (SNP) | VAF 334/1112 reads (30%) | called by muse, mutect2, varscan2
- ORM2 | c.-19C>T | 5'UTR (SNP) | VAF 46/248 reads (19%) | catalogued as rs990021054; called by muse, mutect2, varscan2
- PCTP | c.340-60G>A | Intron (SNP) | VAF 66/217 reads (30%) | catalogued as rs763940158, COSV52122241; called by muse, mutect2
- PDCD6IP | c.2121-53G>A | Intron (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- PDE8A | c.1036+54del | Intron (DEL) | VAF 55/168 reads (33%) | catalogued as rs770158474; called by mutect2, varscan2
- PIGN | c.*77_*79del | 3'UTR (DEL) | VAF 158/334 reads (47%) | called by pindel, varscan2
- PLP1 | c.191+39del | Intron (DEL) | VAF 304/666 reads (46%) | catalogued as rs762304113; called by mutect2, varscan2
- PLXNC1 | c.3126+114del | Intron (DEL) | VAF 254/668 reads (38%) | catalogued as rs1008551666; called by mutect2, varscan2
- POU2F3 | c.-29dup | 5'UTR (INS) | VAF 124/248 reads (50%) | catalogued as rs756729035; called by mutect2, varscan2
- PRKCE | c.2067+37C>T | Intron (SNP) | VAF 259/836 reads (31%) | catalogued as rs182845769; called by muse, mutect2, varscan2
- PRKCI | c.-41del | 5'UTR (DEL) | VAF 51/163 reads (31%) | catalogued as rs762502986; called by mutect2, pindel, varscan2
- PRPF4B | c.2820+85del | Intron (DEL) | VAF 54/418 reads (13%) | catalogued as rs575197055; called by mutect2, varscan2
- PTEN | c.*10del | 3'UTR (DEL) | VAF 222/502 reads (44%) | catalogued as rs756681683; ClinVar: uncertain significance / benign / likely benign; called by mutect2, varscan2
- PTX4 | chr16:1488949 G>A | 5'Flank (SNP) | VAF 77/172 reads (45%) | catalogued as rs1324808983; called by muse, mutect2, varscan2
- RAD54L | c.407+50G>A | Intron (SNP) | VAF 99/291 reads (34%) | catalogued as rs758353347; called by muse, mutect2, varscan2
- RALYL | c.572-64G>A | Intron (SNP) | VAF 310/606 reads (51%) | catalogued as rs1194352578; called by muse, mutect2, varscan2
- RHOT2 | c.1326+10C>A | Intron (SNP) | VAF 98/227 reads (43%) | called by muse, mutect2, varscan2
- SLC25A16 | c.*7del | 3'UTR (DEL) | VAF 287/583 reads (49%) | catalogued as rs754318009; called by mutect2, varscan2
- SLC47A1 | c.740-5dup | Intron (INS) | VAF 168/479 reads (35%) | catalogued as rs373281364; called by mutect2, varscan2
- SLURP2 | c.*57C>T | 3'UTR (SNP) | VAF 38/456 reads (8%) | catalogued as rs750867699, COSV100235731; called by muse, mutect2
- SMAP1 | c.*1669del | 3'UTR (DEL) | VAF 121/288 reads (42%) | catalogued as rs575008239; called by mutect2, varscan2
- SPATA31C1 | n.3360A>T | RNA (SNP) | VAF 80/488 reads (16%) | called by muse, mutect2
- SPRYD4 | c.*2102C>T | 3'UTR (SNP) | VAF 178/355 reads (50%) | catalogued as rs376798037; called by muse, mutect2, varscan2
- STAG3 | c.116+83C>T | Intron (SNP) | VAF 48/141 reads (34%) | called by muse, mutect2, varscan2
- STXBP2 | c.246+41G>A | Intron (SNP) | VAF 264/489 reads (54%) | catalogued as rs758491390; called by muse, mutect2, varscan2
- TANC1 | c.3502+36C>T | Intron (SNP) | VAF 26/320 reads (8%) | catalogued as rs148005014; called by muse, mutect2
- THRA | c.-76G>T | 5'UTR (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- TNFRSF18 | c.*9G>A | 3'UTR (SNP) | VAF 164/296 reads (55%) | catalogued as rs1382412296; called by muse, mutect2, varscan2
- TP63 | c.325-18531del | Intron (DEL) | VAF 168/352 reads (48%) | catalogued as rs1263671418, COSV53217690; called by mutect2, varscan2
- TRAK1 | c.1744+92C>T | Intron (SNP) | VAF 301/975 reads (31%) | catalogued as rs777375066, COSV100410097; called by muse, mutect2, varscan2
- USF2 | c.669-14del | Intron (DEL) | VAF 84/214 reads (39%) | catalogued as rs561899149, COSV55886700; called by mutect2, varscan2
- WDR27 | c.784-50G>A | Intron (SNP) | VAF 40/450 reads (9%) | catalogued as rs763171689; called by muse, mutect2
- YIPF6 | c.58-18del | Intron (DEL) | VAF 312/777 reads (40%) | catalogued as rs750358281; called by mutect2, pindel, varscan2
- ZFC3H1 | c.5256-25_5256-24del | Intron (DEL) | VAF 196/730 reads (27%) | catalogued as rs746761128; called by pindel, varscan2
